FM case AD2005 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/1bccbbd8-9744-4525-9755-14377a42e9ef

Female, 75.8 years: Carcinoma, NOS (ICD-O-3 8010/3); specimen biopsied or resected from the head, face or neck. Tumor nuclei on the sequenced sample's slide: 90% (pathologist estimate recorded by GDC). Sample type: Tumor.
